Surgical pathology report (de-identified scan), TCGA case TCGA-CC-5262, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-5262-01A (Primary Tumor).

[page 1 of 3]
1CB-0-3
Carcinoma, hepatocellular, NOS 8170/3
Site: liver C22.0 1/28/11 hr

ID#:

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____
Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver Tumor	10x10x9 cm		6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₄ N ₀ M ₀		Stage: III	
Notes:			
UUID: B09509A2-A982-4298-AEDF-66BA21C584B8 TCGA-CC-5262-01A-PR Redacted 			

[page 2 of 3]
ID#:

Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic			☒		Storiform						
Necrosis			☒		Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell					Glandular cell		☒			Round Cell					Large Cell				
Spindle Cell					Cell Stratification					Fibroblast					Small Cell				
Keratin					Secretion					Osteoblast					RS Cell/RS Like				
Desmosome					Intracyt. Vacuole					Lipoblast					Inflam. Cell				
Pearl					Gland formation					Myoblast					Plasma Cell				

Cellular Differentiation: Well Moderate ☒ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		☒		
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	

Nuclear Grade:

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Hepatocarcinoma
(moderately differentiated) Grade: III

Comments:

Principal Investigator

Pathologist

Date

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		✓	Streaming		
Mosaic	✓		Storiform		
Necrosis		✓	Fibrosis		
Lymphocytic Infiltration	✓		Palisading		
Vascular Invasion		✓	Cystic Degeneration		
Clusterized	✓		Bleeding		
Alveolar Formation		✓	Myxoid Change		
Indian File		✓	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	✓		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	✓		Fibroblast			Small Cell		
Keratin			Secretion	✓		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	✓		Lipoblast			Inflam. Cell		
Pearl			Gland formation	✓		Myoblast			Plasma Cell		
Otherwise Specified: D ₁ 95%, D ₂ 95%, D ₃ 75%, D ₄ 95%											

2. Cellular Differentiation:

Well	Moderately	Poor
✓		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell		✓		
Mitotic Activity		✓		
Nuclear Grade		I		

Histological Diagnosis: Hepatocellular Carcinoma, G-1

Comments: _____

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 806ec1e4-ec0d-4efb-84b9-b14d605196e5 (TCGA-CC-5262.B09509A2-A902-4298-AEDF-66BA21C584BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).